Somatic mutation profile of tumor specimen ALCH-B0AE-TTP1-B (aliquot ALCH-B0AE-TTP1-B-1-0-D-A81V-36) from ALCHEMIST case ALCH-B0AE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.0 years (22,270 days).
Specimen ALCH-B0AE-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54232e0b-e28c-4a17-90a5-c51a0fde0713.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0AE-NB1-A (Blood Derived Normal), aliquot ALCH-B0AE-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/678b4ef4-13b0-4935-a399-fa21c4a02ca7

The open-access MAF lists 504 somatic variants for this specimen: 339 protein-altering or splice-affecting, 100 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 291, Silent 100, Intron 23, Nonsense Mutation 19, 5'UTR 15, RNA 12, Splice Region 10, Frame Shift Del 9, 3'UTR 9, Splice Site 6, 5'Flank 5, Nonstop Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 49/181 reads (27%) | catalogued as rs373221034, COSV60102332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.458-1G>T p.X153_splice | Splice Site (SNP) | VAF 36/168 reads (21%) | hotspot (GDC flag); catalogued as CS127044, COSV58686546, COSV58687455, COSV58704542; called by muse, mutect2, varscan2
- CDKN2A | c.458-2A>T p.X153_splice | Splice Site (SNP) | VAF 35/169 reads (21%) | hotspot (GDC flag); catalogued as CS127045, CS1414343, COSV58683256, COSV58703271, COSV58726067; called by muse, mutect2, varscan2
- TP53 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 93/206 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABHD12 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 106/238 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as CM147976, COSV59289279, COSV59289723; called by muse, mutect2, varscan2
- ACOT12 | c.1363G>A p.V455I | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); catalogued as rs761607494, COSV100297057; called by muse, mutect2, varscan2
- ACVRL1 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101187896; called by muse, mutect2, varscan2
- AHCYL2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753367425; called by muse, mutect2
- ANO1 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.746); catalogued as rs755874611; called by muse, mutect2, varscan2
- APOE | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs1217176327, COSV52985387; called by muse, mutect2, varscan2
- ATP10B | c.194G>C p.R65T | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs763172033; called by muse, mutect2, varscan2
- BRMS1 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs756789967, COSV60925486; called by muse, mutect2, varscan2
- C3orf62 | c.669G>C p.K223N | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs147619300; called by muse, varscan2
- CA2 | c.623G>T p.W208L | Missense Mutation (SNP) | VAF 74/260 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53405851; called by muse, mutect2, varscan2
- CA4 | c.206G>C p.R69P | Missense Mutation (SNP) | VAF 101/235 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as CM072913, COSV56282434, COSV99039723; called by muse, mutect2, varscan2
- CACNA1B | c.4667C>T p.A1556V | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.19); catalogued as rs199500748, COSV53121317; called by muse, mutect2, varscan2
- CAMLG | c.636C>T p.S212= | Splice Region (SNP) | VAF 25/53 reads (47%) | catalogued as rs1258791126; called by muse, mutect2, varscan2
- CCDC168 | c.16259C>A p.P5420Q | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs778982316, COSV59425584; called by muse, mutect2, varscan2
- CCDC170 | c.1091G>T p.R364L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.198); catalogued as rs773183796; called by muse, mutect2
- CEACAM21 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 65/191 reads (34%) | catalogued as COSV51816236; called by muse, mutect2, varscan2
- COA8 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 93/283 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV56027603; called by muse, mutect2, varscan2
- CRYBG3 | c.2957C>T p.A986V | Missense Mutation (SNP) | VAF 74/117 reads (63%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.244); catalogued as rs909786691; called by muse, mutect2, varscan2
- CSMD3 | c.4306G>A p.D1436N (on ENST00000297405 / NM_001363185.1; = p.D1332N on NM_052900.3) | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52095707, COSV52154546; called by muse, mutect2, varscan2
- CSMD3 | c.3971C>G p.S1324* (on ENST00000297405 / NM_001363185.1; = p.S1220* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 44/597 reads (7%) | catalogued as COSV52168595; called by muse, mutect2
- CYP24A1 | c.249C>A p.H83Q | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383090763; called by muse, mutect2, varscan2
- DDX19B | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55363738; called by muse, mutect2, varscan2
- DNAH11 | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1415369353; called by muse, mutect2
- DPP3 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs369936005; called by muse, mutect2, varscan2
- DPYSL4 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1451195393; called by muse, mutect2
- DYNC1I2 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.836); catalogued as COSV55524243; called by muse, varscan2
- EI24 | c.248G>T p.W83L | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.973); catalogued as COSV99629179; called by muse, mutect2, varscan2
- EP400 | c.2926G>A p.G976R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs965595541, COSV57770127; called by muse, mutect2, varscan2
- EPHA3 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 18/538 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs1483175958; called by muse, mutect2
- ETV5 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1250670377, COSV60504103; called by muse, mutect2
- EVPL | c.3834C>G p.N1278K | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as COSV56910512; called by muse, mutect2, varscan2
- EXO1 | c.191A>G p.N64S | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs755724339; called by muse, mutect2, varscan2
- FAM47B | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 83/144 reads (58%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.736); catalogued as COSV100264282, COSV61452799; called by muse, mutect2, varscan2
- FAM90A1 | c.635A>T p.Q212L | Missense Mutation (SNP) | VAF 51/284 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as COSV100274379; called by muse, mutect2, varscan2
- FLG | c.4828C>T p.R1610W | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs560805546, COSV64238918; called by muse, mutect2, varscan2
- FSHR | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1008534502; called by muse, mutect2, varscan2
- GABRA2 | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.438); catalogued as COSV100734533; called by muse, mutect2
- GAREM2 | c.2447G>A p.R816H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1475278531; called by muse, mutect2
- GOLGA8T | c.634C>A p.Q212K | Missense Mutation (SNP) | VAF 49/294 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs1248934537; called by muse, mutect2, varscan2
- GPR101 | c.809T>A p.V270D | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as COSV99981749; called by muse, mutect2, varscan2
- GRK1 | c.1259G>A p.S420N | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1566698970; called by muse, mutect2, varscan2
- IFT140 | c.2494G>A p.G832R | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs781453055; called by muse, mutect2
- IGFALS | c.1340C>A p.T447K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.402); catalogued as COSV51908121; called by muse, mutect2, varscan2
- IGHG2 | c.51C>A p.S17R | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.588); catalogued as rs373243647; called by muse, mutect2, varscan2
- IGKV2D-26 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 127/274 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs768745981; called by muse, mutect2, varscan2
- KCNA4 | c.1769C>A p.P590H | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV60252475; called by muse, mutect2, varscan2
- KCNH5 | c.1854G>A p.W618* | Nonsense Mutation (SNP) | VAF 51/118 reads (43%) | catalogued as COSV59768149; called by muse, mutect2
- KCNJ3 | c.1377A>T p.L459F | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.014); catalogued as COSV99716128; called by muse, mutect2, varscan2
- KCNT2 | c.2572C>G p.L858V | Missense Mutation (SNP) | VAF 60/330 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV54097421; called by muse, mutect2, varscan2
- KCTD8 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs770111942, COSV63599495; called by muse, mutect2, varscan2
- KDM3B | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as COSV58694744; called by muse, mutect2, varscan2
- KIT | c.1245C>G p.I415M | Missense Mutation (SNP) | VAF 65/345 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55400852; called by muse, mutect2, varscan2
- KRT5 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267603519, COSV52860432; called by muse, mutect2, varscan2
- KYAT3 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.185); catalogued as COSV53099241; called by muse, mutect2
- LARP1B | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 39/192 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as rs772256740; called by muse, mutect2, varscan2
- LCOR | c.1447C>G p.H483D | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV53717096; called by muse, mutect2, varscan2
- LONRF2 | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as rs373553931; called by muse, mutect2
- MACROD2 | c.1069G>T p.G357* (on ENST00000642719; = p.G329* on NM_080676.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 118/387 reads (30%) | catalogued as rs754104922, COSV53984572; called by muse, mutect2, varscan2
- MAGEL2 | c.703C>A p.P235T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0); catalogued as COSV58567599; called by muse, mutect2
- MARK1 | c.1443G>C p.E481D | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs1324407633; called by muse, mutect2, varscan2
- MAST3 | c.3215G>C p.R1072P | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99446083; called by muse, mutect2, varscan2
- MEGF10 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs141706024, COSV99174891; called by muse, mutect2, varscan2
- MGA | c.2218A>T p.T740S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.623); catalogued as rs780781803; called by muse, mutect2, varscan2
- MICU1 | c.775C>T p.R259C (on ENST00000361114 / NM_001195518.2; = p.R265C on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs367648335; called by muse, mutect2, varscan2
- MMP12 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100405119; called by muse, mutect2, varscan2
- MORC1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 84/537 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV51716164; called by muse, varscan2
- MPP6 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs766240383; called by muse, varscan2
- MROH2B | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.137); catalogued as rs1427712030, COSV101270924, COSV68181885, COSV68186148; called by muse, mutect2, varscan2
- MYOM2 | c.4316G>A p.G1439E | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV50707714; called by muse, mutect2, varscan2
- NALCN | c.2065T>C p.C689R | Missense Mutation (SNP) | VAF 7/201 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1321008289, COSV51963731; called by muse, mutect2
- NBPF1 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs1353755078; called by muse, varscan2
- NBR1 | c.1951G>C p.E651Q | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57832462; called by muse, mutect2, varscan2
- NEFM | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as rs770243371; called by muse, mutect2, varscan2
- NEGR1 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV60874687, COSV60874741; called by muse, mutect2, varscan2
- NEK8 | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as rs1238581801, COSV52049302; called by muse, mutect2, varscan2
- NEURL1B | c.1141G>A p.G381S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.33); catalogued as COSV63939876; called by muse, mutect2, varscan2
- NKAPL | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV59199689; called by muse, mutect2
- NOTCH1 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53029104; called by muse, mutect2, varscan2
- OR2M5 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV63545854, COSV63546806; called by muse, mutect2, varscan2
- OR2M7 | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.029); catalogued as COSV100522751; called by muse, mutect2, varscan2
- OR52A5 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV56617005; called by muse, mutect2, varscan2
- OR52B6 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs776969037; called by muse, mutect2
- OR8G1 | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100422285; called by muse, varscan2
- OR8K5 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as rs149739175, COSV57891524; called by muse, mutect2, varscan2
- PCDHB12 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV53396851; called by muse, mutect2, varscan2
- PCNX3 | c.441G>T p.S147= | Splice Region (SNP) | VAF 14/80 reads (18%) | catalogued as COSV58419895; called by muse, mutect2, varscan2
- PKHD1L1 | c.9838G>A p.V3280I | Missense Mutation (SNP) | VAF 29/291 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs369177302, COSV65750642; called by muse, mutect2, varscan2
- PLEKHA6 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs746710062, COSV55334434; called by muse, mutect2, varscan2
- PLXNA4 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs778856713, COSV58129296; called by muse, mutect2, varscan2
- PRKCD | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV100387862; called by muse, mutect2, varscan2
- RGS7 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.967); catalogued as rs772169550, COSV58530462; called by muse, varscan2
- SFTPA1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV100957100; called by muse, mutect2, varscan2
- SI | c.3760-1G>A p.X1254_splice | Splice Site (SNP) | VAF 30/568 reads (5%) | catalogued as rs1279115346; called by muse, mutect2
- SLC12A5 | c.1415C>A p.S472Y (on ENST00000454036 / NM_001134771.2; = p.S449Y on NM_020708.5) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.155); catalogued as COSV54799068; called by muse, mutect2, varscan2
- SLC26A8 | c.1535C>G p.S512C | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV62886181; called by muse, mutect2, varscan2
- SLITRK3 | c.2434C>A p.L812M | Missense Mutation (SNP) | VAF 47/411 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); catalogued as rs766856107; called by muse, mutect2, varscan2
- SRRM2 | c.4595C>T p.P1532L | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as rs772805565, COSV57067995; called by muse, mutect2, varscan2
- SUN3 | c.611G>A p.S204N | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1356122420; called by muse, mutect2, varscan2
- SV2C | c.468C>A p.F156L | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV59217588; called by muse, mutect2, varscan2
- SYCE1 | c.475G>A p.E159K (on ENST00000343131 / NM_001143764.3; = p.E123K on NM_130784.3) | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs868080674; called by muse, mutect2, varscan2
- TBX18 | c.1328A>T p.N443I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs201312372; called by muse, mutect2, varscan2
- TENM4 | c.5570G>T p.R1857L | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV53668380; called by muse, mutect2, varscan2
- TESK2 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1212569883; called by muse, mutect2, varscan2
- TEX15 | c.1786G>A p.V596I (on ENST00000256246; = p.V979I on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.442); catalogued as rs1189419209; called by muse, mutect2
- TLR4 | c.2421C>G p.F807L (on ENST00000355622 / NM_138554.5; = p.F767L on NM_003266.4) | Missense Mutation (SNP) | VAF 130/209 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62923448; called by muse, mutect2, varscan2
- TMEM9 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); catalogued as COSV66243915; called by muse, mutect2, varscan2
- TNR | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 38/150 reads (25%) | catalogued as COSV54873507, COSV54891671; called by muse, mutect2, varscan2
- TRGV8 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 76/294 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.085); catalogued as rs1466898657; called by muse, mutect2
- TRGV8 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs1189813014; called by muse, mutect2
- TRIM6-TRIM34 | c.1963+5G>A | Splice Region (SNP) | VAF 53/187 reads (28%) | catalogued as rs1164548858; called by muse, mutect2, varscan2
- TTN | c.94543C>T p.H31515Y (on ENST00000591111; = p.H24091Y on NM_003319.4) | Missense Mutation (SNP) | VAF 74/332 reads (22%) | PolyPhen probably damaging (0.997); catalogued as rs374666520; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.10514del p.P3505Lfs*6 | Frame Shift Del (DEL) | VAF 46/262 reads (18%) | catalogued as COSV56339653; called by mutect2, pindel, varscan2
- WDR26 | c.2059G>A p.A687T (on ENST00000414423 / NM_001379403.1; = p.A587T on NM_025160.7) | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs370131674; called by muse, mutect2, varscan2
- ZNF225 | c.1826C>T p.S609L | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.904); catalogued as rs1464140205; called by muse, mutect2, varscan2
- ZNF267 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100339875; called by muse, mutect2, varscan2
- ZNF397 | c.1416G>C p.Q472H | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1460771425; called by muse, mutect2, varscan2
- ZNF462 | c.6476A>G p.Y2159C | Missense Mutation (SNP) | VAF 89/153 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52943533; called by muse, mutect2, varscan2
- ZNF479 | c.859C>A p.H287N | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58637651; called by muse, varscan2
- ZNF479 | c.797A>G p.E266G | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs782150943; called by muse, varscan2
- ZNF492 | c.1445G>A p.C482Y | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV71762330; called by muse, mutect2, varscan2
- ZNF721 | c.1773C>G p.H591Q (on ENST00000338977; = p.H603Q on NM_133474.4) | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs782810165; called by muse, mutect2, varscan2
- ZNF780B | c.1301A>G p.Q434R | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.994); catalogued as rs746754234; called by muse, mutect2, varscan2
- ZNF804A | c.1655C>A p.S552Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV56438172, COSV56450498; called by muse, mutect2
- ZSCAN4 | c.212C>G p.S71* | Nonsense Mutation (SNP) | VAF 56/149 reads (38%) | catalogued as COSV58998595; called by muse, mutect2, varscan2
- ABCA10 | c.2504A>G p.N835S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2
- ABCC9 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- AC013489.1 | c.676A>G p.K226E | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ADCY1 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGB | c.392T>A p.L131H | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ADGRB3 | c.2873G>C p.W958S | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL2 | c.4174G>A p.E1392K (on ENST00000370717 / NM_001366005.1; = p.E1336K on NM_012302.4) | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.403); called by muse, mutect2
- AHI1 | c.1598C>T p.T533I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AHNAK | c.12562A>G p.M4188V | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ALDH1A2 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALX1 | c.476T>C p.V159A | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- AMOTL2 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANO5 | c.958G>T p.V320F | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- APOE | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.738); called by muse, varscan2
- ARMH1 | c.716A>G p.Q239R | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- ATP13A3 | c.3612G>T p.W1204C (on ENST00000645319 / NM_001367549.1; = p.W1174C on NM_024524.3) | Missense Mutation (SNP) | VAF 355/571 reads (62%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ATP13A5 | c.996G>A p.M332I | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- BCL11B | c.1892G>A p.G631E (on ENST00000357195 / NM_001282237.2; = p.G560E on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- C2CD5 | c.2136G>A p.M712I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, varscan2
- C3orf62 | c.593A>G p.N198S | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- CACNB2 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CASZ1 | c.4493C>T p.S1498L | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- CD163 | c.2736G>T p.K912N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CHD7 | c.1088A>G p.H363R | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CHRNB3 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- CHST13 | c.753C>A p.H251Q | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- COPE | c.731A>G p.D244G | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- CPA3 | c.736A>T p.I246F | Missense Mutation (SNP) | VAF 36/680 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.117); called by muse, mutect2
- CPT1B | c.2160T>A p.Y720* | Nonsense Mutation (SNP) | VAF 44/175 reads (25%) | called by muse, mutect2, varscan2
- CSPG4 | c.2333C>T p.T778I | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CTAGE6 | c.945G>T p.L315F | Missense Mutation (SNP) | VAF 31/673 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2
- CTNND2 | c.2708T>C p.I903T | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CUL4B | c.1054C>T p.L352F | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.55); called by muse, varscan2
- CYP2C19 | c.53C>A p.S18* | Nonsense Mutation (SNP) | VAF 37/150 reads (25%) | called by muse, mutect2, varscan2
- DHX30 | c.2989G>T p.D997Y (on ENST00000445061 / NM_138615.3; = p.D958Y on NM_014966.3) | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- DLG2 | c.403G>T p.G135* | Nonsense Mutation (SNP) | VAF 77/240 reads (32%) | called by muse, mutect2, varscan2
- DMD | c.10867A>T p.S3623C | Missense Mutation (SNP) | VAF 161/257 reads (63%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DNAH10 | c.363G>C p.M121I (on ENST00000409039; = p.M60I on NM_207437.3) | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH7 | c.1419A>C p.K473N | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- DPPA4 | c.488C>A p.T163K | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- DSCAM | c.4196G>T p.W1399L | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DST | c.19333C>G p.L6445V (on ENST00000361203 / NM_001374722.1; = p.L4142V on NM_015548.5) | Missense Mutation (SNP) | VAF 13/525 reads (2%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2
- EPSTI1 | c.692C>T p.A231V (on ENST00000398762 / NM_001330543.2; = p.A220V on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/234 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- FADS2 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- FAM110A | c.350_351delinsT p.P117Lfs*75 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by pindel, varscan2*
- FAM177B | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 51/382 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FBN1 | c.5573A>T p.N1858I | Missense Mutation (SNP) | VAF 80/446 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBN2 | c.7129G>A p.E2377K | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FCRLA | c.160G>A p.E54K (on ENST00000367959; = p.E31K on NM_032738.4) | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FIGN | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- FLRT3 | c.1550A>C p.Q517P | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FOXD3 | c.413G>C p.S138T | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FOXD3 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- FOXN3 | c.110T>G p.L37R | Missense Mutation (SNP) | VAF 128/331 reads (39%) | called by muse, mutect2, varscan2
- GALNT17 | c.866A>T p.E289V | Missense Mutation (SNP) | VAF 93/278 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- GALT | c.329-3C>T | Splice Region (SNP) | VAF 60/276 reads (22%) | called by muse, mutect2, varscan2
- GFRAL | c.755G>T p.C252F | Missense Mutation (SNP) | VAF 52/358 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GFUS | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- GLIS2 | c.737G>T p.R246L | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLP2R | c.1577G>T p.R526L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GLYAT | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.438); called by muse, mutect2
- GP2 | c.1613G>T p.*538Lext*4 (on ENST00000381362 / NM_001007240.3; = p.*535Lext*4 on NM_001502.4) | Nonstop Mutation (SNP) | VAF 36/206 reads (17%) | called by muse, mutect2, varscan2
- GPHN | c.1250T>C p.I417T (on ENST00000315266 / NM_001377519.1; = p.I450T on NM_020806.5) | Missense Mutation (SNP) | VAF 177/448 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- H1-7 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- HELLS | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- HFM1 | c.1375del p.T459Qfs*22 | Frame Shift Del (DEL) | VAF 52/433 reads (12%) | called by mutect2, pindel, varscan2
- HIPK1 | c.154A>T p.T52S | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HMCN1 | c.6041T>A p.I2014N | Missense Mutation (SNP) | VAF 152/514 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HOXA10 | c.1211C>A p.T404K | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HPS1 | c.778_808del p.R260Cfs*61 | Frame Shift Del (DEL) | VAF 34/145 reads (23%) | called by mutect2, pindel
- ICE1 | c.4127C>A p.S1376Y | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- IFIT5 | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHV4-61 | c.47G>A p.W16* | Nonsense Mutation (SNP) | VAF 46/211 reads (22%) | called by muse, mutect2, varscan2
- IGKV1D-17 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- INPP5J | c.982del p.R328Gfs*57 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- INS | c.230T>C p.L77P | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.03); called by muse, varscan2
- IQSEC3 | c.320C>G p.P107R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.811); called by mutect2, varscan2
- ITGAV | c.2959C>A p.P987T | Missense Mutation (SNP) | VAF 172/398 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- JAKMIP3 | c.700G>C p.G234R | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JPH3 | c.2246G>C p.*749Sext*1 | Nonstop Mutation (SNP) | VAF 13/128 reads (10%) | called by muse, mutect2, varscan2
- KANK3 | c.2306T>G p.I769S | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- KANSL1 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA3 | c.1000G>T p.V334L | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- KCNH5 | c.1852T>A p.W618R | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KDM3B | c.2011G>T p.A671S | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIAA1210 | c.3922del p.Q1308Kfs*45 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | called by mutect2, pindel, varscan2
- KIF26B | c.5943G>T p.R1981S | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- LAMC2 | c.74G>C p.R25T | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- LILRA5 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- LINC02740 | n.217G>T | Splice Region (SNP) | VAF 102/250 reads (41%) | called by muse, mutect2, varscan2
- LTBP1 | c.197C>G p.S66W | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LTBP3 | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- LTK | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.206); called by muse, varscan2
- MACROD2 | c.1069+1G>C p.X357_splice (on ENST00000642719; = p.X329_splice on NM_080676.6 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 118/383 reads (31%) | called by muse, mutect2, varscan2
- MET | c.4164G>C p.E1388D | Missense Mutation (SNP) | VAF 33/287 reads (11%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- MKI67 | c.8569G>A p.A2857T | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2
- MOG | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 56/393 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- MS4A6A | c.524G>T p.C175F | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MT1E | c.55T>A p.C19S | Missense Mutation (SNP) | VAF 13/307 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2
- MTRF1L | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- MUC19 | c.1568G>C p.R523P | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MYT1L | c.61G>T p.V21L | Missense Mutation (SNP) | VAF 32/325 reads (10%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- NCOA6 | c.4883T>C p.V1628A | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- NFE2L2 | c.57G>T p.L19F | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLRP3 | c.1658G>T p.S553I | Missense Mutation (SNP) | VAF 79/385 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOP58 | c.1489A>G p.K497E | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NPAS3 | c.176C>T p.A59V (on ENST00000356141 / NM_001164749.2; = p.A29V on NM_022123.3) | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NSUN3 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 35/442 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2
- NUGGC | c.2326G>A p.G776S | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OCA2 | c.766C>A p.Q256K | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- OR4L1 | c.791G>T p.S264I | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OR56A5 | c.673T>A p.L225M | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR5D16 | c.661G>C p.A221P | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- OR5V1 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAPPA2 | c.2647G>T p.A883S | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCBP1 | c.551A>G p.Q184R | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB10 | c.79G>C p.G27R | Missense Mutation (SNP) | VAF 116/233 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PCDHB14 | c.2078C>A p.A693E | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PCDHGB3 | c.1093G>C p.A365P | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2
- PCLO | c.5831A>G p.E1944G | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCLO | c.3657dup p.L1220Tfs*4 | Frame Shift Ins (INS) | VAF 102/349 reads (29%) | called by mutect2, varscan2
- PDE6G | c.114C>G p.F38L | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PDIA4 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- PDILT | c.1123C>A p.Q375K | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PELI3 | c.189G>C p.Q63H | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PELI3 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- PGBD2 | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHF20 | c.2519G>T p.C840F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIAS1 | c.1038T>A p.C346* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- PLD1 | c.1862A>C p.H621P | Missense Mutation (SNP) | VAF 103/196 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLEKHH1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 22/195 reads (11%) | called by muse, mutect2, varscan2
- PLEKHM2 | c.1530G>C p.E510D | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- POTEG | c.313T>A p.C105S | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- POU4F2 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); called by muse, varscan2
- PPP1R21 | c.11del p.A4Vfs*24 | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | called by mutect2, pindel, varscan2
- PPP2R5D | c.50G>A p.C17Y | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRKD3 | c.1803T>A p.D601E | Missense Mutation (SNP) | VAF 40/391 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.115); called by muse, mutect2
- PRMT2 | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- PRSS12 | c.2040-5C>T | Splice Region (SNP) | VAF 70/238 reads (29%) | called by muse, mutect2, varscan2
- PRSS35 | c.352G>T p.V118F | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PSMA3 | c.652G>C p.G218R | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- PTCH1 | c.744C>T p.L248= | Splice Region (SNP) | VAF 60/258 reads (23%) | called by muse, mutect2, varscan2
- QSOX1 | c.2191T>A p.F731I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- RAB39A | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- RALGDS | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.911); called by muse, mutect2
- RANBP17 | c.3219G>T p.L1073F | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- RAPH1 | c.3032G>A p.G1011E | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- RASSF8 | c.639C>G p.I213M | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.424); called by muse, mutect2
- REG1B | c.145T>A p.Y49N | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.431); called by muse, mutect2
- RGL1 | c.928G>C p.E310Q (on ENST00000360851 / NM_001297672.2; = p.E345Q on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2
- RGPD8 | c.3624G>C p.L1208F | Missense Mutation (SNP) | VAF 36/857 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCAF11 | c.3271G>C p.D1091H | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2
- SCARF1 | c.811A>G p.N271D | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCN7A | c.872-1G>A p.X291_splice | Splice Site (SNP) | VAF 20/132 reads (15%) | called by muse, mutect2, varscan2
- SERPINA11 | c.974A>G p.D325G | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2
- SERPINA9 | c.326C>G p.A109G | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- SLC45A2 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); called by muse, varscan2
- SLC6A3 | c.1811T>A p.V604E | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- SLC6A5 | c.1854del p.P619Qfs*2 | Frame Shift Del (DEL) | VAF 30/315 reads (10%) | called by pindel, varscan2*
- SLC7A13 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SLC7A5 | c.1291-7G>T | Splice Region (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2, varscan2
- SMARCC2 | c.2734A>C p.I912L | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- SNAPIN | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- SOX8 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- SPTA1 | c.6432G>C p.E2144D | Missense Mutation (SNP) | VAF 134/467 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- SRI | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 50/542 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- SRRM4 | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 71/315 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, varscan2
- ST6GALNAC3 | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 89/192 reads (46%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ST8SIA6 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- STX18 | c.759G>C p.V253= | Splice Region (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- SYDE2 | c.3162del p.K1055Rfs*8 | Frame Shift Del (DEL) | VAF 92/278 reads (33%) | called by pindel, varscan2
- TAAR1 | c.532T>C p.C178R | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TAS2R14 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TBC1D9 | c.3722C>G p.T1241S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- TDRD3 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- TEX13A | c.1137C>G p.D379E | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFEC | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- THSD7B | c.4489G>T p.G1497C (on ENST00000272643; = p.G1495C on NM_001316349.2) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TIFAB | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM131L | c.2314G>C p.E772Q | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TMEM38B | c.112+1G>T p.X38_splice | Splice Site (SNP) | VAF 34/98 reads (35%) | called by muse, mutect2, varscan2
- TPH2 | c.1293G>C p.K431N | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TRAPPC3L | c.47A>T p.K16I | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- TRBV20-1 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 25/213 reads (12%) | called by muse, mutect2, varscan2
- TRIM50 | c.116G>T p.C39F | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRMT61B | c.1199A>T p.Q400L | Missense Mutation (SNP) | VAF 103/203 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TSEN34 | c.44G>C p.G15A | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- TTLL13P | c.1350T>A p.S450= | Splice Region (SNP) | VAF 65/169 reads (38%) | called by muse, mutect2, varscan2
- TTN | c.26915C>T p.S8972L (on ENST00000591111; = p.S8045L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | PolyPhen benign (0.116); called by muse, varscan2
- TTN | c.3194C>G p.T1065S (on ENST00000591111; = p.T1019S on NM_003319.4) | Missense Mutation (SNP) | VAF 31/292 reads (11%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USH2A | c.11517G>T p.Q3839H | Missense Mutation (SNP) | VAF 65/333 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- UTP20 | c.7868T>A p.I2623N | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- VN1R4 | c.379G>T p.V127F | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- VPREB1 | c.234C>A p.S78R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- VWF | c.6604T>A p.S2202T | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- WASHC2C | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- WDR53 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 76/317 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- WNK4 | c.3161C>G p.S1054* | Nonsense Mutation (SNP) | VAF 29/205 reads (14%) | called by muse, mutect2, varscan2
- ZAN | c.7718G>T p.C2573F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFYVE26 | c.3884C>T p.S1295L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZGRF1 | c.622T>A p.C208S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.01); called by muse, mutect2
- ZIC1 | c.1054C>G p.H352D | Missense Mutation (SNP) | VAF 57/247 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF28 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZNF337 | c.1833G>A p.W611* | Nonsense Mutation (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- ZNF337 | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- ZNF699 | c.105G>T p.L35F | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF703 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF761 | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- ZNF837 | c.529C>G p.P177A | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- ZNF839 | c.287C>G p.S96C (on ENST00000558850 / NM_001267827.1; = p.S212C on NM_018335.5) | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- ZNF99 | c.1898C>A p.S633Y | Missense Mutation (SNP) | VAF 92/297 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.416); called by muse, varscan2
- ACAD8 | c.765G>A p.V255= | Silent (SNP) | VAF 7/168 reads (4%) | called by muse, mutect2
- ADCY2 | c.258G>T p.L86= | Silent (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- AGA | c.882G>A p.Q294= | Silent (SNP) | VAF 26/513 reads (5%) | called by muse, mutect2
- ANKRD13C | c.1368C>T p.S456= | Silent (SNP) | VAF 32/274 reads (12%) | called by muse, mutect2, varscan2
- ANO5 | c.564T>A p.T188= | Silent (SNP) | VAF 87/218 reads (40%) | called by muse, mutect2, varscan2
- APC | c.7047A>T p.S2349= | Silent (SNP) | VAF 53/91 reads (58%) | called by muse, mutect2, varscan2
- ARID1A | c.5274C>T p.P1758= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs764320974; called by muse, mutect2, varscan2
- BAG4 | c.180C>T p.T60= | Silent (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
- CD163 | c.157C>T p.L53= | Silent (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- CDH18 | c.768C>A p.I256= | Silent (SNP) | VAF 39/180 reads (22%) | called by muse, mutect2, varscan2
- CDH19 | c.2130G>T p.P710= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as COSV50959787, COSV50978581; called by muse, mutect2, varscan2
- CFAP54 | c.8580G>T p.L2860= | Silent (SNP) | VAF 34/120 reads (28%) | called by muse, mutect2, varscan2
- CFAP74 | c.3534C>T p.D1178= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs1388238386; called by muse, mutect2, varscan2
- CYP2J2 | c.696C>A p.V232= | Silent (SNP) | VAF 82/232 reads (35%) | catalogued as rs568654777, COSV64606187; called by muse, mutect2, varscan2
- DENND4B | c.1374G>A p.P458= | Silent (SNP) | VAF 30/133 reads (23%) | catalogued as rs761732924, COSV63408384; called by muse, mutect2, varscan2
- DIABLO | c.351G>T p.V117= (on ENST00000443649 / NM_001278303.1; = p.V190= on NM_019887.6) | Silent (SNP) | VAF 47/328 reads (14%) | called by muse, mutect2, varscan2
- DNAH17 | c.861C>G p.L287= | Silent (SNP) | VAF 40/160 reads (25%) | catalogued as rs1232504149; called by muse, mutect2, varscan2
- DPP6 | c.495G>C p.V165= (on ENST00000377770 / NM_001364500.2; = p.V103= on NM_001936.5) | Silent (SNP) | VAF 43/174 reads (25%) | catalogued as COSV59607069; called by muse, mutect2, varscan2
- EFL1 | c.1215G>A p.E405= | Silent (SNP) | VAF 33/110 reads (30%) | called by muse, mutect2, varscan2
- ERVV-2 | c.1416C>G p.L472= | Silent (SNP) | VAF 54/192 reads (28%) | called by muse, mutect2, varscan2
- FAIM2 | c.849G>A p.S283= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs142589017; called by muse, mutect2, varscan2
- FGGY | c.858G>T p.T286= | Silent (SNP) | VAF 21/135 reads (16%) | catalogued as rs142638637; called by muse, mutect2, varscan2
- FOLH1 | c.777A>G p.L259= | Silent (SNP) | VAF 74/276 reads (27%) | called by muse, mutect2, varscan2
- FOXN2 | c.1014C>T p.H338= | Silent (SNP) | VAF 13/123 reads (11%) | catalogued as rs372325337; called by muse, mutect2, varscan2
- FRRS1L | c.408G>C p.L136= | Silent (SNP) | VAF 38/397 reads (10%) | called by muse, mutect2, varscan2
- FSHR | c.654T>A p.S218= | Silent (SNP) | VAF 54/427 reads (13%) | called by muse, mutect2, varscan2
- GPHN | c.375G>T p.L125= | Silent (SNP) | VAF 48/376 reads (13%) | called by muse, mutect2, varscan2
- GSDMB | c.510G>A p.L170= | Silent (SNP) | VAF 24/220 reads (11%) | catalogued as COSV100522675, COSV58780952, COSV58781411; called by muse, mutect2, varscan2
- GSR | c.1326C>G p.T442= | Silent (SNP) | VAF 99/254 reads (39%) | called by muse, mutect2, varscan2
- GSR | c.1248C>T p.F416= | Silent (SNP) | VAF 72/338 reads (21%) | catalogued as rs1186937230; called by muse, mutect2, varscan2
- H2AC21 | c.294C>T p.L98= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV58612175; called by muse, mutect2, varscan2
- HCN1 | c.507G>A p.E169= | Silent (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- IARS1 | c.1947T>G p.L649= | Silent (SNP) | VAF 55/107 reads (51%) | called by muse, mutect2, varscan2
- INF2 | c.2016C>G p.L672= | Silent (SNP) | VAF 23/104 reads (22%) | called by muse, mutect2, varscan2
- KLF5 | c.816G>A p.Q272= | Silent (SNP) | VAF 88/322 reads (27%) | catalogued as COSV66614835; called by muse, mutect2, varscan2
- LEPR | c.90T>A p.P30= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as rs560511914; called by muse, mutect2, varscan2
- LMCD1 | c.558C>T p.V186= | Silent (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- LRRC4C | c.126G>A p.V42= | Silent (SNP) | VAF 26/189 reads (14%) | called by muse, mutect2, varscan2
- LVRN | c.153C>G p.L51= | Silent (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- MGA | c.5103G>A p.V1701= | Silent (SNP) | VAF 33/224 reads (15%) | called by muse, mutect2, varscan2
- MGRN1 | c.1551G>A p.E517= | Silent (SNP) | VAF 36/87 reads (41%) | called by muse, mutect2, varscan2
- MRPS22 | c.678C>T p.V226= (on ENST00000310776 / NM_001363893.1; = p.V227= on NM_020191.4) | Silent (SNP) | VAF 49/818 reads (6%) | called by muse, mutect2
- MTUS1 | c.528T>C p.H176= | Silent (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- MUC4 | c.2766C>T p.I922= | Silent (SNP) | VAF 22/424 reads (5%) | catalogued as COSV62186476; called by muse, mutect2
- MYC | c.1131G>A p.L377= (on ENST00000377970; = p.L392= on NM_002467.6) | Silent (SNP) | VAF 33/57 reads (58%) | called by muse, mutect2, varscan2
- NAB1 | c.1203G>A p.Q401= | Silent (SNP) | VAF 109/277 reads (39%) | called by muse, mutect2, varscan2
- NHSL1 | c.57C>G p.L19= | Silent (SNP) | VAF 10/278 reads (4%) | called by muse, mutect2
- NMUR2 | c.141C>T p.P47= | Silent (SNP) | VAF 142/257 reads (55%) | catalogued as rs995955791; called by muse, mutect2, varscan2
- NOTCH2 | c.6403C>T p.L2135= | Silent (SNP) | VAF 48/316 reads (15%) | called by muse, mutect2, varscan2
- OCA2 | c.765C>A p.T255= | Silent (SNP) | VAF 83/213 reads (39%) | called by muse, mutect2, varscan2
- OR2A25 | c.420C>T p.C140= | Silent (SNP) | VAF 93/369 reads (25%) | catalogued as rs781005878; called by muse, mutect2, varscan2
- OR2T11 | c.786C>T p.F262= | Silent (SNP) | VAF 55/163 reads (34%) | catalogued as COSV58185753; called by muse, mutect2, varscan2
- OR2T2 | c.102C>A p.S34= | Silent (SNP) | VAF 83/962 reads (9%) | catalogued as COSV61618736; called by muse, mutect2
- OR5L2 | c.498C>A p.I166= | Silent (SNP) | VAF 45/161 reads (28%) | catalogued as COSV65724406, COSV65725288; called by muse, mutect2, varscan2
- PAPPA | c.4272G>T p.G1424= | Silent (SNP) | VAF 66/256 reads (26%) | called by muse, mutect2, varscan2
- PCDHB13 | c.1821C>G p.L607= | Silent (SNP) | VAF 26/139 reads (19%) | called by muse, mutect2, varscan2
- PCNX2 | c.732G>A p.E244= | Silent (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- PDZD2 | c.7335A>T p.S2445= | Silent (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- POU3F3 | c.36G>A p.G12= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs1176427240; called by muse, mutect2, varscan2
- RAB40C | c.483C>T p.F161= | Silent (SNP) | VAF 31/132 reads (23%) | called by muse, mutect2, varscan2
- RARS2 | c.1341C>T p.F447= | Silent (SNP) | VAF 133/474 reads (28%) | called by muse, mutect2, varscan2
- REEP3 | c.204G>A p.L68= | Silent (SNP) | VAF 12/93 reads (13%) | called by muse, varscan2
- SARDH | c.1936C>T p.L646= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs554611953; called by muse, mutect2, varscan2
- SCEL | c.1749A>G p.T583= (on ENST00000349847 / NM_144777.3; = p.T563= on NM_003843.4) | Silent (SNP) | VAF 82/293 reads (28%) | catalogued as rs1478476443; called by muse, mutect2, varscan2
- SCN3A | c.1041A>T p.P347= | Silent (SNP) | VAF 155/330 reads (47%) | called by muse, mutect2, varscan2
- SDE2 | c.891A>T p.S297= | Silent (SNP) | VAF 39/156 reads (25%) | called by muse, mutect2, varscan2
- SFI1 | c.2298G>A p.R766= (on ENST00000400288 / NM_001007467.3; = p.R735= on NM_014775.4) | Silent (SNP) | VAF 62/199 reads (31%) | catalogued as COSV63475586; called by muse, mutect2, varscan2
- SLC18A2 | c.1245G>T p.V415= | Silent (SNP) | VAF 21/231 reads (9%) | called by muse, mutect2
- SLC45A2 | c.270G>T p.S90= | Silent (SNP) | VAF 46/124 reads (37%) | called by muse, varscan2
- SLC7A10 | c.213C>T p.S71= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs948286236; called by mutect2, varscan2
- SNX20 | c.504C>G p.L168= | Silent (SNP) | VAF 31/98 reads (32%) | called by muse, mutect2, varscan2
- SORCS1 | c.1419A>T p.A473= | Silent (SNP) | VAF 37/104 reads (36%) | called by muse, mutect2, varscan2
- SPTA1 | c.5916T>A p.T1972= | Silent (SNP) | VAF 68/464 reads (15%) | catalogued as COSV63756492; called by muse, mutect2, varscan2
- STAU2 | c.747T>C p.S249= (on ENST00000524300 / NM_001164380.2; = p.S217= on NM_014393.2) | Silent (SNP) | VAF 31/334 reads (9%) | called by muse, mutect2
- SYDE2 | c.3156G>A p.L1052= | Silent (SNP) | VAF 107/299 reads (36%) | catalogued as COSV100416133; called by muse, varscan2
- TAF8 | c.159C>T p.A53= | Silent (SNP) | VAF 72/415 reads (17%) | catalogued as rs778638815; called by muse, mutect2, varscan2
- TAX1BP1 | c.2100G>A p.V700= | Silent (SNP) | VAF 60/248 reads (24%) | catalogued as COSV99386612; called by muse, mutect2, varscan2
- TECPR1 | c.2160G>T p.R720= | Silent (SNP) | VAF 11/139 reads (8%) | called by muse, mutect2
- TENM3 | c.2541T>C p.S847= | Silent (SNP) | VAF 32/239 reads (13%) | called by muse, mutect2, varscan2
- TENM3 | c.6429C>G p.L2143= | Silent (SNP) | VAF 23/171 reads (13%) | called by muse, mutect2, varscan2
- TEX13A | c.279G>A p.L93= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV100781803; called by muse, mutect2, varscan2
- TF | c.957C>T p.H319= | Silent (SNP) | VAF 32/185 reads (17%) | catalogued as rs565363550, COSV99396384; called by muse, mutect2, varscan2
- TMEM63C | c.426T>C p.F142= | Silent (SNP) | VAF 80/205 reads (39%) | called by muse, mutect2, varscan2
- TNR | c.1149G>A p.T383= | Silent (SNP) | VAF 110/319 reads (34%) | catalogued as rs549257371, COSV54898748; called by muse, mutect2, varscan2
- TNXB | c.840C>T p.C280= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as COSV100926143; called by muse, mutect2, varscan2
- TRIM3 | c.321A>G p.V107= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- TRMT112 | c.327C>T p.I109= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV50007054; called by muse, mutect2, varscan2
- TRPC4 | c.705T>C p.N235= | Silent (SNP) | VAF 77/232 reads (33%) | catalogued as rs953286247; called by muse, mutect2, varscan2
- TRPM2 | c.4210C>A p.R1404= | Silent (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.72942G>A p.L24314= (on ENST00000591111; = p.L16890= on NM_003319.4) | Silent (SNP) | VAF 30/327 reads (9%) | called by muse, mutect2
- USP26 | c.652C>A p.R218= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV63709614; called by muse, varscan2
- UTF1 | c.135G>T p.A45= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1166425764; called by muse, mutect2, varscan2
- VENTX | c.483G>T p.G161= | Silent (SNP) | VAF 30/83 reads (36%) | called by muse, mutect2, varscan2
- VIPAS39 | c.1002G>A p.V334= | Silent (SNP) | VAF 66/311 reads (21%) | called by muse, mutect2, varscan2
- XPO1 | c.2196C>A p.I732= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs748714556; called by muse, mutect2, varscan2
- ZNF280B | c.621C>A p.T207= | Silent (SNP) | VAF 23/136 reads (17%) | called by muse, mutect2, varscan2
- ZNF479 | c.813T>C p.C271= | Silent (SNP) | VAF 58/194 reads (30%) | called by muse, varscan2
- ZNF541 | c.3498C>G p.T1166= | Silent (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- ZNF652 | c.135C>T p.D45= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as rs1450677692; called by muse, mutect2, varscan2
- ZNF726 | c.1020C>A p.P340= | Silent (SNP) | VAF 72/183 reads (39%) | called by muse, mutect2, varscan2
- ABCC8 | c.4199-26C>G | Intron (SNP) | VAF 57/154 reads (37%) | called by muse, mutect2, varscan2
- AC073316.1 | n.123C>A | RNA (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- ACER3 | c.*16A>T | 3'UTR (SNP) | VAF 34/214 reads (16%) | catalogued as rs782703815; called by muse, varscan2
- AKT1S1 | c.-1G>A | 5'UTR (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- AL035696.1 | n.406T>A | RNA (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- APBB1 | c.1588+78T>A | Intron (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- ASB13 | c.-13G>T | 5'UTR (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- ASB5 | c.-2C>A | 5'UTR (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- ATP1A3 | c.3053-66G>T | Intron (SNP) | VAF 51/126 reads (40%) | called by muse, mutect2, varscan2
- ATP6V1A | c.83-288G>T | Intron (SNP) | VAF 42/394 reads (11%) | called by muse, mutect2, varscan2
- C2orf72 | c.*213G>T | 3'UTR (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- C9orf24 | c.*103G>C | 3'UTR (SNP) | VAF 54/108 reads (50%) | called by muse, mutect2, varscan2
- CASP7 | c.-161G>C | 5'UTR (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- CLEC10A | c.675+14G>A | Intron (SNP) | VAF 54/92 reads (59%) | called by muse, mutect2, varscan2
- CPEB1 | c.-49C>T | 5'UTR (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2
- DEFB121 | n.187A>T | RNA (SNP) | VAF 46/181 reads (25%) | called by muse, mutect2, varscan2
- DNASE1L3 | c.-1G>C | 5'UTR (SNP) | VAF 34/58 reads (59%) | called by muse, mutect2, varscan2
- DNASE1L3 | c.-2G>A | 5'UTR (SNP) | VAF 33/56 reads (59%) | catalogued as rs1290502200; called by muse, mutect2, varscan2
- DPP9 | c.2244+317G>T | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- DYRK4 | c.-82T>C | 5'UTR (SNP) | VAF 40/142 reads (28%) | called by muse, mutect2, varscan2
- GNAS | chr20:58889146 C>G | 5'Flank (SNP) | VAF 5/25 reads (20%) | catalogued as rs865947378; called by muse, mutect2
- GSDME | c.697+1710C>G | Intron (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- HERC2P2 | n.644A>C | RNA (SNP) | VAF 52/201 reads (26%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1118C>T | RNA (SNP) | VAF 32/480 reads (7%) | catalogued as rs755098712; called by muse, mutect2
- HSPB6 | c.-2G>T | 5'UTR (SNP) | VAF 30/100 reads (30%) | called by muse, varscan2
- IGLV7-46 | c.-4C>G | 5'UTR (SNP) | VAF 72/228 reads (32%) | called by muse, mutect2, varscan2
- KIF1A | c.*23C>T | 3'UTR (SNP) | VAF 16/20 reads (80%) | catalogued as rs531276835; called by muse, mutect2, varscan2
- LEMD3 | c.2493+28A>G | Intron (SNP) | VAF 69/234 reads (29%) | called by muse, mutect2, varscan2
- LINC00840 | n.106C>A | RNA (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- LINC01548 | n.555C>T | RNA (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- LITAF | c.*1582A>G | 3'UTR (SNP) | VAF 77/164 reads (47%) | catalogued as rs1296376697; called by muse, mutect2, varscan2
- LRRC7 | c.647+35216A>G | Intron (SNP) | VAF 26/196 reads (13%) | catalogued as rs750937664; called by muse, mutect2, varscan2
- MANBA | c.-20C>T | 5'UTR (SNP) | VAF 28/106 reads (26%) | catalogued as rs775535548; called by muse, mutect2, varscan2
- MFSD4B | c.*232C>T | 3'UTR (SNP) | VAF 22/99 reads (22%) | called by muse, mutect2, varscan2
- MIF4GD | chr17:75272278 G>T | 5'Flank (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- MS4A8 | c.534+3053G>C | Intron (SNP) | VAF 14/147 reads (10%) | catalogued as rs1392150934; called by muse, mutect2
- OR51F5P | n.572G>T | RNA (SNP) | VAF 23/135 reads (17%) | called by muse, mutect2, varscan2
- ORC6 | c.66-23G>A | Intron (SNP) | VAF 23/228 reads (10%) | called by muse, mutect2, varscan2
- PABPC1P2 | n.735G>T | RNA (SNP) | VAF 20/157 reads (13%) | called by muse, mutect2, varscan2
- PAX6 | c.142-131T>C | Intron (SNP) | VAF 44/344 reads (13%) | called by muse, mutect2, varscan2
- PLOD1 | c.-24C>T | 5'UTR (SNP) | VAF 5/54 reads (9%) | catalogued as rs1258702661; called by muse, mutect2
- PNKD | c.237-16405G>T | Intron (SNP) | VAF 34/56 reads (61%) | called by muse, mutect2, varscan2
- POLR2M | c.-2G>C | 5'UTR (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- PRKCE | c.1437+225C>A | Intron (SNP) | VAF 122/282 reads (43%) | catalogued as rs938015012; called by muse, varscan2
- PRMT2 | c.490-54A>G | Intron (SNP) | VAF 11/68 reads (16%) | catalogued as rs888366149; called by muse, mutect2, varscan2
- RN7SL495P | chr15:22613700 A>G | 5'Flank (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- RNU6-713P | chr12:40550535 A>G | 3'Flank (SNP) | VAF 36/120 reads (30%) | called by muse, varscan2
- RPL26L1 | chr5:172955007 A>C | 5'Flank (SNP) | VAF 20/214 reads (9%) | called by muse, mutect2
- SETDB1 | c.3669+22C>G | Intron (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- SNX22 | c.460+111A>T | Intron (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
- SRI | c.*28C>T | 3'UTR (SNP) | VAF 77/314 reads (25%) | called by muse, mutect2, varscan2
- STS | c.-69T>C | 5'UTR (SNP) | VAF 44/79 reads (56%) | called by muse, mutect2, varscan2
- TCAF2 | c.1615+142T>C | Intron (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*1460C>A | 3'UTR (SNP) | VAF 46/236 reads (19%) | called by muse, mutect2, varscan2
- TRAP1 | c.472-14G>A | Intron (SNP) | VAF 6/49 reads (12%) | catalogued as rs368607096, COSV99892919; called by muse, mutect2, varscan2
- TSHR | c.170+28G>T | Intron (SNP) | VAF 83/203 reads (41%) | called by muse, mutect2, varscan2
- TTN | c.10360+3895A>T | Intron (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2
- UBE3C | c.1331+1962G>A | Intron (SNP) | VAF 12/30 reads (40%) | catalogued as rs373556735; called by muse, varscan2
- UBTFL2 | n.567G>T | RNA (SNP) | VAF 26/151 reads (17%) | called by mutect2, varscan2
- UCN2 | c.-2C>T | 5'UTR (SNP) | VAF 15/29 reads (52%) | catalogued as rs142687169; called by muse, mutect2, varscan2
- UMPS | c.*3806G>C | 3'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- WBP1LP2 | n.244C>A | RNA (SNP) | VAF 54/159 reads (34%) | called by muse, mutect2, varscan2
- ZC3HAV1 | c.1471+286G>A | Intron (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- ZFPM2 | n.313G>T | RNA (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- ZNF687 | chr1:151281558 C>A | 5'Flank (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
